Somatic mutation profile of tumor specimen SM-JU357 (aliquot 7316UP-2100) from CPTAC case C846363, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen SM-JU357: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be4e2432-a69b-42b0-93e6-0f4ff4506360.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105216 (Blood Derived Normal), aliquot 7316UP-2100-1105216; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d55e8f39-995e-4886-8e08-17cec791327e

The open-access MAF lists 56 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Nonsense Mutation 4, Intron 3, RNA 2, Splice Region 1, 3'UTR 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG12 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 135/838 reads (16%) | PolyPhen probably damaging (1); catalogued as rs553349150; called by muse, mutect2, varscan2
- ANK1 | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 118/224 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs764141047, COSV55886773; called by muse, mutect2, varscan2
- CABP2 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs375360165, COSV53708769; called by muse, mutect2, varscan2
- CD163L1 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 158/380 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs779416105, COSV58016469; called by muse, mutect2, varscan2
- CDS1 | c.642C>T p.F214= | Splice Region (SNP) | VAF 16/65 reads (25%) | catalogued as rs375840719; called by muse, mutect2, varscan2
- CHP2 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 95/416 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs756989190, COSV55649492; called by muse, mutect2, varscan2
- DEFB114 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.005); catalogued as rs141697166, COSV59038413; called by muse, mutect2, varscan2
- DNAJC1 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 14/492 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.632); catalogued as rs1161494392, COSV65410803; called by muse, mutect2
- DSC2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 139/325 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs374707462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 358/896 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs777847026; called by muse, mutect2, varscan2
- KEL | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 58/610 reads (10%) | catalogued as COSV100787323; called by muse, mutect2
- LAMB1 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 43/186 reads (23%) | catalogued as rs1370434147, COSV55963202, COSV55969793; called by muse, mutect2, varscan2
- LARP1B | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs150798326; called by muse, mutect2, varscan2
- LRGUK | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs764953610, COSV53633892; called by muse, mutect2, varscan2
- MMP3 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); catalogued as rs149156238; called by muse, mutect2, varscan2
- MRGPRX4 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 114/224 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs778327061, COSV58589894; called by muse, mutect2, varscan2
- NIPSNAP2 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 156/623 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753851867; called by muse, mutect2, varscan2
- OR7C1 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as rs772802995, COSV50183672; called by muse, mutect2
- PFAS | c.3205C>T p.R1069* | Nonsense Mutation (SNP) | VAF 115/301 reads (38%) | catalogued as rs368793879; called by muse, mutect2, varscan2
- PIK3R1 | c.1915C>T p.R639* (on ENST00000521381 / NM_181523.3; = p.R369* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 82/219 reads (37%) | catalogued as COSV57126125; called by muse, mutect2, varscan2
- TTN | c.87049G>A p.E29017K (on ENST00000591111; = p.E21593K on NM_003319.4) | Missense Mutation (SNP) | VAF 100/263 reads (38%) | PolyPhen probably damaging (0.994); catalogued as COSV60229470; called by muse, mutect2, varscan2
- AC013489.1 | c.785A>G p.E262G | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CAMTA1 | c.3085G>A p.A1029T | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRNE | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 18/610 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- EYA1 | c.482C>G p.T161R | Missense Mutation (SNP) | VAF 195/442 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- FHAD1 | c.1712C>A p.A571D | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, varscan2
- HCAR3 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 226/588 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- MGAM2 | c.4807G>T p.D1603Y | Missense Mutation (SNP) | VAF 48/653 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- OR2B11 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 95/263 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKDC | c.11884C>T p.R3962W | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF207 | c.1487G>C p.W496S | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- RTF1 | c.296A>G p.D99G | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SHISA6 | c.761A>G p.N254S | Missense Mutation (SNP) | VAF 94/224 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); called by muse, mutect2
- SLC38A1 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLIT2 | c.3718T>G p.F1240V | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TRUB1 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 79/112 reads (71%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.27314G>A p.G9105D (on ENST00000591111; = p.G8178D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 159/333 reads (48%) | PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- XIRP1 | c.3596G>T p.C1199F | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF507 | c.1772T>C p.I591T | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM18 | c.1164A>G p.Q388= | Silent (SNP) | VAF 28/150 reads (19%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.5808A>G p.R1936= (on ENST00000310343 / NM_001378025.1; = p.R1587= on NM_014715.4) | Silent (SNP) | VAF 160/323 reads (50%) | called by muse, mutect2, varscan2
- FGF6 | c.591G>A p.P197= | Silent (SNP) | VAF 101/240 reads (42%) | catalogued as rs776204115; called by muse, mutect2, varscan2
- KRTAP13-2 | c.204G>A p.T68= | Silent (SNP) | VAF 80/201 reads (40%) | catalogued as rs746030923; called by muse, mutect2, varscan2
- NXF1 | c.1473G>C p.L491= | Silent (SNP) | VAF 49/146 reads (34%) | called by muse, mutect2, varscan2
- PKP2 | c.2070C>T p.I690= | Silent (SNP) | VAF 216/571 reads (38%) | catalogued as rs538127756, COSV50755620; called by muse, mutect2, varscan2
- SLC1A7 | c.375G>A p.T125= | Silent (SNP) | VAF 87/473 reads (18%) | catalogued as rs371121273; called by muse, mutect2, varscan2
- SLC4A10 | c.315C>T p.T105= | Silent (SNP) | VAF 76/173 reads (44%) | catalogued as rs374865086; called by muse, mutect2, varscan2
- SYNDIG1L | c.705C>T p.N235= | Silent (SNP) | VAF 152/226 reads (67%) | catalogued as rs764855912, COSV100526538; called by muse, mutect2, varscan2
- TTN | c.13209C>T p.T4403= (on ENST00000591111; = p.T4357= on NM_003319.4) | Silent (SNP) | VAF 73/155 reads (47%) | called by muse, mutect2, varscan2
- ADH4 | c.*84A>C | 3'UTR (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- DPF3 | chr14:72894105 del AG | 5'Flank (DEL) | VAF 54/101 reads (53%) | catalogued as rs766420993; called by mutect2, pindel*, varscan2
- EPS8L2 | c.895+72A>C | Intron (SNP) | VAF 30/110 reads (27%) | catalogued as rs753850480; called by muse, mutect2, varscan2
- FAM183BP | n.459C>T | RNA (SNP) | VAF 49/204 reads (24%) | catalogued as rs777630638; called by muse, mutect2, varscan2
- FAM197Y1 | n.374G>A | RNA (SNP) | VAF 50/790 reads (6%) | catalogued as rs776135058; called by muse, mutect2
- GALNT9 | c.1077+270G>A | Intron (SNP) | VAF 89/188 reads (47%) | catalogued as rs1429858126; called by muse, mutect2, varscan2
- GPI | c.123-349G>A | Intron (SNP) | VAF 63/429 reads (15%) | called by muse, mutect2, varscan2
